Somatic mutation profile of tumor specimen TCGA-BJ-A28Z-01A (aliquot TCGA-BJ-A28Z-01A-11D-A16O-08) from TCGA case TCGA-BJ-A28Z, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 46.3 years (16,912 days).
Specimen TCGA-BJ-A28Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 561aef01-a544-4581-9566-203d5b816dd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A28Z-10A (Blood Derived Normal), aliquot TCGA-BJ-A28Z-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4492771e-0aba-4e97-981f-889dd4efd443

The open-access MAF lists 23 somatic variants for this specimen: 12 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 11, Silent 11, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSK | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV66170216; called by muse, mutect2, varscan2
- B3GNT5 | c.533G>A p.W178* | Nonsense Mutation (SNP) | VAF 33/129 reads (26%) | catalogued as COSV58476617; called by muse, mutect2, varscan2
- BFSP2 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs200573601, COSV56588655; called by muse, mutect2, varscan2
- EHD1 | c.1114C>G p.Q372E | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as COSV57735934; called by muse, mutect2, varscan2
- GPC5 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV65617219; called by muse, varscan2
- ITGB1 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV56484855; called by muse, mutect2, varscan2
- KIF15 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58163506; called by muse, mutect2, varscan2
- MAP4K4 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56337110; called by muse, mutect2, varscan2
- NIPAL3 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV50234843; called by muse, mutect2, varscan2
- OR4D9 | c.812T>A p.I271N | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV61435125; called by muse, mutect2, varscan2
- SMARCC2 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs767594606, COSV57222176; called by muse, mutect2, varscan2
- TNFSF4 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV56057215; called by muse, mutect2, varscan2
- ABCA3 | c.1143C>T p.L381= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV57057410; called by muse, mutect2, varscan2
- CGAS | c.516G>A p.L172= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV64808707; called by muse, mutect2, varscan2
- CSGALNACT2 | c.489C>T p.L163= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs1448232250, COSV65675743; called by muse, mutect2, varscan2
- FZD1 | c.618C>A p.G206= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV55312635; called by muse, mutect2, varscan2
- GOPC | c.301C>T p.L101= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV50003209; called by muse, mutect2, varscan2
- MYOCD | c.1656G>A p.Q552= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV58500882; called by muse, mutect2, varscan2
- NUBP1 | c.630G>C p.R210= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV51594922; called by muse, mutect2, varscan2
- STAR | c.291G>A p.K97= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs772621298, COSV52418139; called by muse, mutect2, varscan2
- TMTC2 | c.801C>T p.L267= | Silent (SNP) | VAF 38/209 reads (18%) | catalogued as COSV58278383; called by muse, mutect2, varscan2
- TRIML1 | c.120C>T p.L40= | Silent (SNP) | VAF 72/327 reads (22%) | catalogued as COSV60195960; called by muse, mutect2, varscan2
- VWA7 | c.771G>A p.P257= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs201850397, COSV65155542; called by muse, mutect2, varscan2
